Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6356, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6356-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. PROSTATE
- B. RIGHT PELVIC LYMPH NODES
- C. LEFT PELVIC LYMPH NODES

TCGA - G9 - 6356

SPECIMEN(S):

- A. PROSTATE
- B. RIGHT PELVIC LYMPH NODES
- C. LEFT PELVIC LYMPH NODES

GROSS DESCRIPTION:

A. PROSTATE

Received fresh labeled with the patient's identification and designated "prostate" is a resected prostate gland weighing 49 g and measuring 5-cm from right to left, 4-cm from anterior to posterior, and 3.3-cm from apex to base. The external capsule is red smooth and intact. Ink code: Apex-red, anterior-orange, base-blue, posterior-black, right-green, left-yellow. The apex and base are removed from the specimen yielding a new weight of 22 g. The specimen is serially sectioned from apex to base. Cut section shows firm light tan fibrous parenchyma. The right and left seminal vesicle measure 1.6 x 1.4 x 0.4 cm, and 2.5 x 1.4 x 0.4 cm, respectively. Both are bisected to show beige tan cystic tissue. The right and left vas measure 2.3 x 0.7 cm, and 1.8 x 0.6 cm, respectively. Both are sectioned to show firm tan tube structure. A portion of the specimen is submitted for tissue procurement, the remainder is entirely submitted for microscopic evaluation:

- A1-A2: Right apex
- A3-A4: Left Apex
- A5: Level 1 right anterior
- A6: Level 1 right posterior
- A7: Level 1 left anterior
- A8: Level 1 left posterior
- A9-A10: Level 2 capsule, right side
- A11-A12: Level 2 capsule, left side
- A13: Right lateral base
- A14-A16: Right base
- A17: Right base with proximal urethral margin
- A18: Left base with proximal urethral margin
- A19-A22: Left base
- A23-A24: Left lateral base
- A25: Right posterior base
- A26: Left posterior base
- A27: Right seminal vesicle, right vas
- A28: Left seminal vesicle, left vas

B. RIGHT PELVIC LYMPH NODES

Received in formalin in a container labeled with the patient's identification and designated "right pelvic lymph nodes" are multiple fragments of adipose tissue measuring 5.6 x 3.1 x 0.5 cm in aggregate. Two possible lymph nodes are identified measuring 2.5 x 0.8 x 0.5 cm and 0.9 x 0.7 x 0.5 cm. The entire specimen is submitted:

- B1: One bisected lymph node
- B2: One lymph node
- B3-B5: Remainder of the specimen

C. LEFT PELVIC LYMPH NODES

Received in formalin in a container labeled with the patient's identification and designated "left pelvic lymph nodes" is a fragment of fibroadipose tissue measuring 6.7 x 2 x 1.2 cm. One lymph node is identified measuring 2.2 x 0.3 x 0.3 cm, submitted in cassette C1. The remainder of the specimen is submitted, C2-C4.

DIAGNOSIS:

A. PROSTATE, PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA, GLEASON GRADE 4 + 5 WITH GRADE 3 PATTERN ALSO PRESENT (SEE NOTE FOR GRADE ASSESSMENT), INVOLVING RIGHT AND LEFT LOBES OF PROSTATE AND AN ESTIMATED 75% OF THE PROSTATE GLAND.
- EXTRAPROSTATIC EXTENSION AND SEMINAL VESICLE INVASION IDENTIFIED.
- ADENOCARCINOMA PRESENT AT THE MARGIN IN MULTIPLE LOCATIONS (SEE NOTE).

[page 2 of 2]
NOTE: The tumor in this prostate was high grade and high volume with an aggressive pattern of infiltration at the capsular surface. The vast majority of the tumor was Gleason grade 4. In some areas there was a significant component (>5%) of grade 5 tumor, while in other areas there was a significant component (>5%) of grade 3 tumor. As an individual tumor pattern the grade 3 and grade 5 tumor components were each more 5% of the total tumor, but certainly each was much less than the grade 4 component. Adenocarcinoma was present at the inked surgical margin of resection in multiple foci that are defined in the synoptic report. The seminal vesicles showed extensive involvement by tumor and also showed deposition of amorphous material consistent with amyloidosis.

B. LYMPH NODES, RIGHT PELVIC, EXCISION:

- FOUR LYMPH NODES WITH NO EVIDENCE OF METASTATIC ADENOCARCINOMA (0/4).

C. LYMPH NODES, LEFT PELVIC, EXCISION:

- ONE LYMPH NODE WITH NO EVIDENCE OF METASTATIC ADENOCARCINOMA (0/1).

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma

Multicentricity: Yes

Gland Involvement: 75%

Gleason Grade/Sum:: Grade 4 + 5 , Sum 9 /10; Tertiary grade 3

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: Yes

Left

Right

Muscular Wall Invasion: Yes

Lumen Invasion: No

Periprostatic Fat Involved: Yes

Details: RIGHT POSTERIOR

Bladder Neck Involved: No

Margins Involvement: Yes

Location: slides A8 (left posterior 8 mm), A17 (left base 1 mm), A18 (right base 1 mm)

Linear Distance: Diffuse (>10mm or Multifocal)

Frozen Performed: No

Lymph Nodes: Negative Right 0 / 4 Left 0 / 1

Other Pathologic Findings: seminal vesicle amyloidosis

Pathological Staging (pTNM): T 3b N 0 M X

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

Source: NCI Genomic Data Commons file ae6fa17d-dcaa-414b-ab1d-5cf31f7d99d5 (TCGA-G9-6356.818A2716-CA81-4534-BA13-A0FE3A18B2E9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).